Gene-level copy-number profile of tumor specimen ALCH-B05X-TTP1-A from ALCHEMIST case ALCH-B05X, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.9 years (22,227 days).
Specimen ALCH-B05X-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0da38122-571b-4638-ae50-b577d6e371ab.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B05X-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/96c64d31-f16a-408b-945a-0c5e62e5df31

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 8,339; copy number 2: 47,240; copy number 3: 274; copy number 4: 2,510; copy number 5: 1; copy number 6: 7.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,492,300–2,494,479, 2 genes (within-gene range 0–2): AL139246.1, AL139246.4.
- chr2:241,881,363–242,088,457, 8 genes (within-gene range 0–1): LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2.
- chr6:167,795,530–167,825,145, 2 genes (within-gene range 0–1): AL009178.2, AL009178.3.
- chr8:12,310,962–12,345,776, 3 genes: DEFB130A, RNA5SP254, DEFB108E.
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr14:100,538,939–100,540,409, 1 gene (within-gene range 0–2): AL845552.2.
- chr15:74,311,516–74,319,688, 1 gene (within-gene range 0–2): AC023300.2.
- chr17:18,244,815–18,268,828, 3 genes (within-gene range 0–2): FLII, MIEF2, AC127537.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,500,512, 7 genes, copy number 6: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr8:12,290,071–12,296,180, 1 gene, copy number 5: DEFB131D.

Autosomal genes at a single copy (total copy number 1): 7,617. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
